Gene-level copy-number profile of tumor specimen C3L-04757-03 from CPTAC case C3L-04757, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G1; Age at diagnosis: 68.1 years (24,886 days).
Specimen C3L-04757-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d2febc80-87bd-4d49-a4f4-907650d9ed8d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04757-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/f031c264-246e-416a-a9c4-daf9e5ce5bac

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 508; copy number 1: 8; copy number 2: 2,650; copy number 3: 984; copy number 4: 32,871; copy number 5: 1,517; copy number 6: 14,230; copy number 7: 362; copy number 8: 4,679; copy number 9: 334; copy number 10: 483; copy number 11: 3; copy number 12: 1; copy number 13: 12; copy number 14: 34; copy number 15: 13; copy number 16: 123; copy number 17: 49; copy number 18: 22; copy number 19: 1; copy number 26: 4; copy number 119: 8; copy number 187: 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr19:20,432,552–20,571,095, 2 genes (within-gene range 0–4): AC008554.1, BNIP3P23.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 899 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:197,791,226–198,123,232, 15 genes, copy number 9–11: LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1.
- chr5:27,217,714–45,895,970, 269 genes, copy number 9 (broad region; genes not listed).
- chr11:86,649–333,688, 30 genes, copy number 9: OR4F2P, AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P, BET1L, SCGB1C1, ODF3, AC069287.2, RIC8A, MIR6743, SIRT3, PSMD13, AC136475.10, NLRP6, AC136475.3, PGGHG, IFITM5, AC136475.6, IFITM2, AC136475.2, IFITM1, AC136475.1, IFITM3, AC136475.4, AC136475.8, AC136475.7, AC136475.5, AC136475.9.
- chr13:68,289,679–68,331,613, 3 genes, copy number 9: ELL2P3, HNRNPA1P18, RPL37P21.
- chr13:70,459,464–81,691,072, 126 genes, copy number 9–10 (broad region; genes not listed).
- chr13:85,065,087–86,277,262, 7 genes, copy number 9: LINC00375, LINC00351, SLITRK6, AL162373.1, MOB1AP1, AL354994.1, DDX6P2.
- chr13:87,219,004–114,337,626, 367 genes, copy number 10 (broad region; genes not listed).
- chr16:58,231,157–60,928,541, 40 genes, copy number 9–16: CCDC113, PRSS54, GINS3, RNU6-269P, AC009118.1, RNU6-1110P, AC009118.2, LINC02137, NDRG4, RNU6-103P, SETD6, CNOT1, AC009118.3, SNORA46, SNORA50A, SNORA50A, AC010287.1, SLC38A7, AC012183.1, GOT2, AC106793.1, RNU6-1155P, RN7SL143P, GEMIN8P2, RPL12P36, AC092378.1, Metazoa_SRP, RPS27P27, AC092121.1, RNU4-58P, DUXAP11, APOOP5, LINC02141, AC009094.1, AC009081.2, AC018554.1, NPAP1L, AC009081.1, GNPATP, AC009169.1.
- chr19:28,294,093–30,038,181, 42 genes, copy number 14–187: AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
